CCDI case PBCKHR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6480ec5f-c602-4a18-aa32-2ddcf7ee5248

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Meningioma, malignant: ICD-O-3 morphology code: 9530/3; Tissue or organ of origin: Cerebral meninges; Age at diagnosis: 9.7 years (3,549 days).

Biospecimens (2 samples)
- Sample 0DVPOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPOZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
